Somatic mutation profile of tumor specimen C3L-03348-03 (aliquot CPT0167050034) from CPTAC case C3L-03348, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 37.6 years (13,721 days).
Specimen C3L-03348-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88e44413-a205-4dcb-8738-2336870f7de2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03348-31 (Blood Derived Normal), aliquot CPT0167070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf2f952b-56d9-4f65-befe-57f955670dab

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/238 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- D2HGDH | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV58320312; called by muse, mutect2
- KLF14 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs1052511554; called by muse, mutect2
- TMEM200A | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 14/126 reads (11%) | catalogued as rs267600806; called by muse, mutect2, varscan2
- NLRP12 | c.1587C>T p.D529= | Silent (SNP) | VAF 78/607 reads (13%) | catalogued as rs781712648, COSV60743835, COSV60758270; called by muse, mutect2, varscan2
- PRKCSH | c.1530C>T p.A510= | Silent (SNP) | VAF 28/364 reads (8%) | catalogued as rs573119093; called by muse, mutect2
- TOMM40 | c.375G>A p.G125= | Silent (SNP) | VAF 26/232 reads (11%) | called by muse, varscan2
- ASB9P1 | n.383G>A | RNA (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
